Gene-level copy-number profile of tumor specimen TCGA-25-1319-01A from TCGA case TCGA-25-1319, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.3 years (26,786 days).
Specimen TCGA-25-1319-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.11cc2243-9785-4894-a8de-52d32cd4e466.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1319-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/295a2866-cdfa-4ac4-89c1-89cd5f45ee63

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 309; copy number 1: 387; copy number 2: 11,045; copy number 3: 25,724; copy number 4: 18,560; copy number 5: 1,888; copy number 6: 569; copy number 7: 252; copy number 8: 181; copy number 9: 184; copy number 10: 149; copy number 11: 1; copy number 12: 106; copy number 13: 42; copy number 15: 30; copy number 16: 221; copy number 17: 72; copy number 18: 16; copy number 19: 13; copy number 22: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-1319-01A-01D-0452-01): tumor purity 0.89, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 309 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–12,015,193, 309 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,266 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,306,368–37,474,411, 22 genes, copy number 9 (within-gene range 5–9): SH3D21, EVA1B, AL591845.1, STK40, LSM10, RNU4-27P, OSCP1, SNORA63C, MRPS15, CSF3R, FTLP18, AL596257.1, AC117945.2, AC117945.1, GRIK3, AL031430.1, AL353604.1, MIR4255, RNU6-636P, RNA5SP43, RPS29P6, LINC01137.
- chr1:39,081,316–39,487,177, 1 gene, copy number 9 (within-gene range 5–9): MACF1.
- chr1:39,226,670–43,156,396, 128 genes, copy number 8–12 (broad region; genes not listed).
- chr1:43,171,652–43,171,712, 1 gene, copy number 8: MIR6733.
- chr2:113,970,719–114,420,302, 7 genes, copy number 7–16: LINC01191, AC110769.1, U3, AC010982.2, AC010982.1, SEPHS1P7, RNU2-41P.
- chr2:114,828,432–114,835,588, 2 genes, copy number 9: DPP10-AS3, DPP10-AS2.
- chr8:12,703,066–13,044,456, 10 genes, copy number 12–16: OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P.
- chr8:13,147,389–13,207,125, 2 genes, copy number 12: AC106845.1, Y_RNA.
- chr8:29,110,573–29,140,729, 1 gene, copy number 8: AC108449.1.
- chr8:65,155,407–66,197,315, 16 genes, copy number 18: RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967.
- chr8:66,562,175–74,029,079, 125 genes, copy number 9–17 (within-gene range 3–17) (broad region; genes not listed).
- chr8:115,408,496–132,760,712, 232 genes, copy number 7–16 (broad region; genes not listed).
- chr11:73,214,998–78,574,874, 174 genes, copy number 8–22 (within-gene range 2–22) (broad region; genes not listed).
- chr12:53,739,611–56,103,505, 135 genes, copy number 7–19 (within-gene range 3–19) (broad region; genes not listed).
- chr12:85,781,892–85,882,992, 3 genes, copy number 7: AC137768.1, RASSF9, NTS.
- chr12:85,958,686–86,016,441, 2 genes, copy number 13: AC016993.1, AC139697.1.
- chr19:9,959,561–11,197,791, 68 genes, copy number 10–11 (broad region; genes not listed).
- chr19:12,195,015–15,145,318, 171 genes, copy number 10–16 (broad region; genes not listed).
- chr19:16,283,359–17,553,839, 77 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr19:29,606,283–31,655,461, 34 genes, copy number 9: POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471.
- chr19:37,235,507–38,587,564, 55 genes, copy number 8 (within-gene range 2–8): AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1.

Autosomal genes at a single copy (total copy number 1): 387. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
